Somatic mutation profile of tumor specimen TARGET-20-PARRDD-09A (aliquot TARGET-20-PARRDD-09A-01D) from TARGET case TARGET-20-PARRDD, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.2 years (4,446 days).
Specimen TARGET-20-PARRDD-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d25ecf3-174a-4fb1-870f-377f359696a4.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARRDD-14A (Bone Marrow Normal), aliquot TARGET-20-PARRDD-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0acb6b9-2418-4705-93b8-72e28b8efc69

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STAG2 | c.328C>T p.R110* | Nonsense Mutation (SNP) | VAF 83/220 reads (38%) | catalogued as COSV54351672; called by muse, mutect2, varscan2
- TPR | c.6002A>G p.Y2001C | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
